Somatic mutation profile of tumor specimen C3N-01524-01 (aliquot CPT0077290009) from CPTAC case C3N-01524, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 61.8 years (22,558 days).
Specimen C3N-01524-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a8dc0e8b-2d63-4bb2-b979-3a55518e7970.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01524-71 (Blood Derived Normal), aliquot CPT0077410002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b7e2c920-6a01-4329-a213-497a97365d95

The open-access MAF lists 124 somatic variants for this specimen: 91 protein-altering or splice-affecting, 20 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 20, Nonsense Mutation 7, 3'UTR 6, Intron 5, Frame Shift Del 5, Translation Start Site 2, Frame Shift Ins 2, RNA 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.332G>A p.S111N | Missense Mutation (SNP) | VAF 109/276 reads (39%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen benign (0.072); catalogued as rs869025631, CD141834, CM951280, HM971583, COSV56542714, COSV56543921; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CEMP1 | c.76C>A p.L26I | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as COSV99566116; called by muse, mutect2, varscan2
- CEP41 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 126/355 reads (35%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs782784827, COSV56219159; called by muse, mutect2, varscan2
- CHRNA2 | c.860T>C p.F287S | Missense Mutation (SNP) | VAF 133/422 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1060503073; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLSTN3 | c.2162G>A p.R721Q | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs148818256, COSV99867181; called by muse, mutect2, varscan2
- CNTN3 | c.2237C>A p.T746N | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.296); catalogued as COSV55185594; called by muse, mutect2, varscan2
- CP | c.2536G>C p.V846L | Missense Mutation (SNP) | VAF 54/167 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.324); catalogued as rs1321940071; called by muse, mutect2, varscan2
- DPYSL4 | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 55/229 reads (24%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.954); catalogued as COSV58308937; called by muse, mutect2, varscan2
- HPS3 | c.980C>A p.T327K | Missense Mutation (SNP) | VAF 50/213 reads (23%) | SIFT tolerated (0.83); PolyPhen benign (0.007); catalogued as COSV56054075; called by muse, mutect2, varscan2
- IGLV4-3 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 45/297 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.387); catalogued as rs754142164; called by muse, mutect2, varscan2
- KIF13A | c.4235A>G p.Q1412R | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs771426174; called by muse, mutect2, varscan2
- KRTAP9-4 | c.143G>T p.C48F | Missense Mutation (SNP) | VAF 149/426 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as rs1336276656, COSV100484848; called by muse, mutect2, varscan2
- LAMA1 | c.3638G>T p.R1213L | Missense Mutation (SNP) | VAF 28/329 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV101057747, COSV99081360; called by muse, mutect2
- MUC17 | c.6628A>C p.M2210L | Missense Mutation (SNP) | VAF 76/235 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.011); catalogued as rs1016884814; called by muse, mutect2, varscan2
- MYL7 | c.68C>T p.S23F | Missense Mutation (SNP) | VAF 69/237 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV56267371; called by muse, mutect2, varscan2
- PACS2 | c.241G>A p.V81M | Missense Mutation (SNP) | VAF 45/151 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as rs1209362754; called by muse, mutect2, varscan2
- PPFIA2 | c.1700C>A p.S567Y | Missense Mutation (SNP) | VAF 78/265 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.323); catalogued as COSV61035926; called by muse, mutect2, varscan2
- PRMT8 | c.974C>A p.S325Y | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV54212189; called by muse, mutect2, varscan2
- PRPF8 | c.5624A>G p.H1875R | Missense Mutation (SNP) | VAF 60/415 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV59261977, COSV59266339; called by muse, mutect2, varscan2
- RHOB | c.41G>T p.G14V | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99695119; called by muse, mutect2
- RTTN | c.4105G>A p.A1369T | Missense Mutation (SNP) | VAF 51/153 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as COSV99731035; called by muse, mutect2, varscan2
- TTN | c.6388G>A p.E2130K (on ENST00000591111; = p.E2084K on NM_003319.4) | Missense Mutation (SNP) | VAF 44/398 reads (11%) | PolyPhen probably damaging (0.994); catalogued as rs762914675, COSV60092129; called by muse, mutect2, varscan2
- UBE2L3 | c.43C>G p.R15G | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as COSV100641576; called by muse, mutect2
- ZNF527 | c.482G>C p.R161T | Missense Mutation (SNP) | VAF 54/170 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.048); catalogued as COSV62236139; called by muse, mutect2, varscan2
- ACY3 | c.217T>G p.F73V | Missense Mutation (SNP) | VAF 93/274 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- AKAP12 | c.2608G>T p.E870* | Nonsense Mutation (SNP) | VAF 38/224 reads (17%) | called by muse, mutect2, varscan2
- AOPEP | c.2083A>T p.K695* (on ENST00000375315 / NM_001193329.1; = p.K596* on NM_032823.5) | Nonsense Mutation (SNP) | VAF 75/254 reads (30%) | called by muse, mutect2, varscan2
- ATP5IF1 | c.296T>G p.I99S | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- BIVM-ERCC5 | c.4120A>C p.T1374P | Missense Mutation (SNP) | VAF 107/317 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- CAMTA1 | c.3131A>C p.K1044T | Missense Mutation (SNP) | VAF 75/234 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- CCDC9 | c.1411T>A p.F471I | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2
- CDK13 | c.2861A>C p.K954T | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CIPC | c.976A>T p.K326* | Nonsense Mutation (SNP) | VAF 86/232 reads (37%) | called by muse, mutect2, varscan2
- CIRBP | c.213dup p.V72Cfs*45 | Frame Shift Ins (INS) | VAF 68/251 reads (27%) | called by mutect2, pindel, varscan2
- CNDP2 | c.973G>A p.G325R | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- CNDP2 | c.974G>T p.G325V | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- CPLX4 | c.313dup p.D105Gfs*8 | Frame Shift Ins (INS) | VAF 43/144 reads (30%) | called by mutect2, pindel, varscan2
- CTNNA1 | c.1628G>T p.G543V | Missense Mutation (SNP) | VAF 126/658 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CUBN | c.343T>A p.S115T | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CYFIP2 | c.2794_2795del p.F932Rfs*58 (on ENST00000616178 / NM_001291722.2; = p.F907Rfs*58 on NM_014376.4) | Frame Shift Del (DEL) | VAF 66/329 reads (20%) | called by mutect2, pindel, varscan2
- DDX46 | c.32G>T p.R11L | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- DEPDC1 | c.165C>A p.D55E | Missense Mutation (SNP) | VAF 81/296 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAJC11 | c.940T>G p.F314V | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- DSCAM | c.1237T>C p.F413L | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- EXOSC2 | c.773A>T p.Y258F | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- FAM120B | c.1638G>T p.M546I | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.39); called by muse, mutect2
- FSIP2 | c.14243T>C p.I4748T | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- GPHN | c.1664T>A p.L555H (on ENST00000315266 / NM_001377519.1; = p.L588H on NM_020806.5) | Missense Mutation (SNP) | VAF 74/304 reads (24%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- IRAG1 | c.263C>A p.P88H | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNF1 | c.597G>T p.M199I | Missense Mutation (SNP) | VAF 24/173 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- KCNH3 | c.1690del p.E564Sfs*76 | Frame Shift Del (DEL) | VAF 41/121 reads (34%) | called by mutect2, pindel*
- KCNH5 | c.629A>C p.Y210S | Missense Mutation (SNP) | VAF 29/159 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KCTD9 | c.593_599del p.S198Yfs*11 | Frame Shift Del (DEL) | VAF 56/270 reads (21%) | called by mutect2, pindel, varscan2
- KIF20B | c.1937T>A p.V646D | Missense Mutation (SNP) | VAF 54/179 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- KIF5C | c.1044del p.E349Rfs*8 | Frame Shift Del (DEL) | VAF 27/90 reads (30%) | called by mutect2, pindel, varscan2
- KRTAP5-11 | c.336C>A p.C112* | Nonsense Mutation (SNP) | VAF 219/697 reads (31%) | called by muse, mutect2, varscan2
- LLGL1 | c.3049A>T p.T1017S | Missense Mutation (SNP) | VAF 96/275 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAP1A | c.3745C>T p.H1249Y | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by mutect2, varscan2
- MEGF11 | c.1936T>A p.S646T | Missense Mutation (SNP) | VAF 49/212 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- MTHFSD | c.349C>G p.Q117E (on ENST00000360900 / NM_001159377.2; = p.Q116E on NM_022764.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/288 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYOM1 | c.2941G>A p.G981R | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); called by mutect2, varscan2
- NCAPG | c.2852G>T p.R951I | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- NOMO1 | c.1068A>T p.K356N | Missense Mutation (SNP) | VAF 46/212 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- P4HA2 | c.288C>G p.D96E | Missense Mutation (SNP) | VAF 61/281 reads (22%) | SIFT tolerated (0.82); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PHF20 | c.1092del p.E364Dfs*7 | Frame Shift Del (DEL) | VAF 52/212 reads (25%) | called by mutect2, pindel, varscan2
- PIKFYVE | c.1145C>A p.P382H | Missense Mutation (SNP) | VAF 89/262 reads (34%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRRC2B | c.2255T>C p.L752P | Missense Mutation (SNP) | VAF 36/228 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- PSEN1 | c.722T>C p.L241P | Missense Mutation (SNP) | VAF 49/257 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEPTIN9 | c.826T>C p.F276L (on ENST00000427177 / NM_001113491.2; = p.F258L on NM_006640.4) | Missense Mutation (SNP) | VAF 123/391 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SI | c.2210G>C p.G737A | Missense Mutation (SNP) | VAF 104/364 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- SLC37A3 | c.452A>G p.N151S | Missense Mutation (SNP) | VAF 67/226 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SMTNL1 | c.1098C>G p.F366L (on ENST00000399154; = p.F403L on NM_001105565.2) | Missense Mutation (SNP) | VAF 45/158 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SOSTDC1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 50/157 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); called by muse, mutect2
- SOX2 | c.103A>T p.K35* | Nonsense Mutation (SNP) | VAF 55/352 reads (16%) | called by muse, mutect2, varscan2
- SPRED3 | c.1129G>T p.V377L | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- STAG1 | c.300C>A p.S100= | Splice Region (SNP) | VAF 61/194 reads (31%) | called by muse, mutect2, varscan2
- TACC2 | c.7954C>A p.P2652T (on ENST00000334433; = p.P730T on NM_006997.4) | Missense Mutation (SNP) | VAF 75/327 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- TACR3 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- TAOK2 | c.1241C>G p.S414C | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TBC1D2 | c.359T>A p.I120N | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- TFEC | c.173C>A p.S58* | Nonsense Mutation (SNP) | VAF 18/68 reads (26%) | called by muse, mutect2
- THSD7B | c.1293T>A p.C431* | Nonsense Mutation (SNP) | VAF 27/85 reads (32%) | called by muse, mutect2
- TSPOAP1 | c.4796G>A p.G1599D | Missense Mutation (SNP) | VAF 51/193 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- TUBGCP3 | c.2496G>C p.R832S | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- UBE2A | c.122T>G p.F41C | Missense Mutation (SNP) | VAF 91/142 reads (64%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USP21 | c.748C>A p.P250T | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- USP29 | c.2245C>G p.Q749E | Missense Mutation (SNP) | VAF 57/182 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- WDR47 | c.1202A>G p.E401G (on ENST00000369962 / NM_001142551.2; = p.E402G on NM_014969.5) | Missense Mutation (SNP) | VAF 79/249 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ZMYM4 | c.2642A>C p.D881A | Missense Mutation (SNP) | VAF 115/381 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- ZPBP | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 79/238 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- ZSWIM5 | c.3200G>T p.S1067I | Missense Mutation (SNP) | VAF 36/262 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ABCC11 | c.855C>T p.C285= | Silent (SNP) | VAF 33/239 reads (14%) | catalogued as rs138005798, COSV100750500; called by muse, mutect2, varscan2
- ATP2B2 | c.1701G>T p.L567= (on ENST00000352432; = p.L533= on NM_001683.5) | Silent (SNP) | VAF 37/83 reads (45%) | called by muse, mutect2
- CCIN | c.1125G>A p.G375= | Silent (SNP) | VAF 49/205 reads (24%) | catalogued as rs17851732, COSV100631678, COSV58725995; called by muse, mutect2, varscan2
- CUBN | c.1440A>C p.G480= | Silent (SNP) | VAF 110/316 reads (35%) | called by muse, mutect2, varscan2
- DGAT2 | c.1023C>A p.P341= | Silent (SNP) | VAF 15/133 reads (11%) | called by muse, mutect2, varscan2
- DLGAP2 | c.1023G>A p.K341= | Silent (SNP) | VAF 45/159 reads (28%) | catalogued as rs371562156; called by muse, mutect2, varscan2
- FRMPD4 | c.3138A>T p.G1046= | Silent (SNP) | VAF 87/132 reads (66%) | called by muse, mutect2, varscan2
- GAB4 | c.1503C>T p.S501= | Silent (SNP) | VAF 53/298 reads (18%) | catalogued as rs755347977, COSV68754459; called by muse, mutect2, varscan2
- GLI2 | c.3942C>T p.S1314= (on ENST00000361492 / NM_001374353.1; = p.S1331= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/108 reads (15%) | called by muse, mutect2, varscan2
- GPHN | c.1665C>A p.L555= (on ENST00000315266 / NM_001377519.1; = p.L588= on NM_020806.5) | Silent (SNP) | VAF 74/303 reads (24%) | called by muse, mutect2, varscan2
- IFFO2 | c.1302G>A p.T434= | Silent (SNP) | VAF 43/132 reads (33%) | catalogued as COSV62913255; called by muse, mutect2, varscan2
- JUNB | c.381C>T p.G127= | Silent (SNP) | VAF 40/128 reads (31%) | catalogued as rs776344055; called by muse, mutect2, varscan2
- KLHDC7A | c.1956G>A p.A652= | Silent (SNP) | VAF 125/362 reads (35%) | catalogued as rs1035779858; called by muse, mutect2, varscan2
- MARVELD1 | c.189C>T p.F63= | Silent (SNP) | VAF 123/409 reads (30%) | catalogued as rs1171788759; called by muse, mutect2, varscan2
- NEURL2 | c.834T>C p.L278= | Silent (SNP) | VAF 56/151 reads (37%) | called by muse, mutect2, varscan2
- RYR2 | c.8019G>A p.A2673= | Silent (SNP) | VAF 31/264 reads (12%) | catalogued as rs745484020, COSV63711534; called by muse, mutect2, varscan2
- TADA2A | c.1299C>T p.F433= | Silent (SNP) | VAF 25/68 reads (37%) | called by muse, mutect2, varscan2
- TBC1D9 | c.60C>A p.A20= | Silent (SNP) | VAF 84/268 reads (31%) | called by muse, varscan2
- TRIM3 | c.921A>C p.R307= | Silent (SNP) | VAF 39/340 reads (11%) | called by muse, mutect2, varscan2
- UTP20 | c.1896C>T p.P632= | Silent (SNP) | VAF 28/86 reads (33%) | called by muse, mutect2, varscan2
- ANKLE2 | c.1700+37C>G | Intron (SNP) | VAF 58/208 reads (28%) | called by muse, mutect2, varscan2
- BRSK2 | c.91+21024C>A | Intron (SNP) | VAF 4/9 reads (44%) | catalogued as COSV100373144; called by muse, mutect2, varscan2
- CASZ1 | c.506-85_506-78delinsA | Intron (DEL) | VAF 15/56 reads (27%) | called by pindel, varscan2*
- CHRNA4 | c.*3184G>T | 3'UTR (SNP) | VAF 38/268 reads (14%) | called by muse, varscan2
- CHRNA4 | c.*3177C>T | 3'UTR (SNP) | VAF 34/237 reads (14%) | called by muse, varscan2
- GYS1 | c.*918A>G | 3'UTR (SNP) | VAF 153/498 reads (31%) | catalogued as rs1484203468; called by muse, mutect2, varscan2
- NAT8L | c.*51C>T | 3'UTR (SNP) | VAF 21/49 reads (43%) | catalogued as rs1465923459; called by muse, varscan2
- PDIA3P1 | n.1265G>T | RNA (SNP) | VAF 81/247 reads (33%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159236 G>A | 5'Flank (SNP) | VAF 15/100 reads (15%) | catalogued as rs761417825; called by muse, mutect2, varscan2
- SAMHD1 | c.1154+49G>T | Intron (SNP) | VAF 47/144 reads (33%) | called by muse, mutect2, varscan2
- TUBB8P7 | n.894+216C>G | Intron (SNP) | VAF 117/338 reads (35%) | catalogued as rs556213255; called by muse, mutect2, varscan2
- UMPS | c.*1306G>A | 3'UTR (SNP) | VAF 42/135 reads (31%) | called by muse, mutect2, varscan2
- VAPB | c.*6170A>G | 3'UTR (SNP) | VAF 53/411 reads (13%) | catalogued as rs1172185375; called by muse, mutect2, varscan2
